Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67N, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67N-01A (Primary Tumor).

[page 1 of 5]
MRN
Name
Encounter Number

Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Final

Source of Specimen

- A. LEFT PELVIC LYMPH NODES - FS-
- B. RIGHT PELVIC LYMPH NODES - FS-
- C. LEFT PELVIC LYMPH NODES - NFS-
- D. RIGHT PELVIC LYMPH NODES - NFS-
- E. PROSTATE GLAND, SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES - FS-
NO TUMOR SEEN IN FOUR LYMPH NODES (0/4).
- B. RIGHT PELVIC LYMPH NODES - FS-
NO TUMOR SEEN IN FOUR LYMPH NODES (0/4).
- C. LEFT PELVIC LYMPH NODES - NFS-
NO TUMOR SEEN IN MULTIPLE FRAGMENTS OF LYMPH NODE.
- D. RIGHT PELVIC LYMPH NODES - NFS-
NO TUMOR SEEN IN MULTIPLE FRAGMENTS OF LYMPH NODE.
- E. PROSTATE GLAND, SEMINAL VESICLES AND VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE WITH UNILATERAL EXTENSION INTO
EXTRAPROSTATIC SOFT TISSUE.

TUMOR SITE: RIGHT AND LEFT, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 24 GRAMS. SIZE: 4 x 3 x 3 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: NOT PRESENT.

Prepared for

path ICD 8-3
Adenocarcinoma NOS 8140/3
C61.9
Adenocarcinoma, acinar 8140/3
Site: Prostate NOS C61.9
JES 5/9/13

Criteria	W 4/22/13	Y	No
Diagnosis Discrepancy	White P=3	MM	✓
PIRPA Discrepancy			
Case in (c) (rel):			

[page 2 of 5]
SEVERITY IN EXTENT OF TUMOR: 2 /5.
(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT PRESENT.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: pT3a, pN0, pMX.
(N0: negative node; N1: positive regional node)

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT MARGINS OF PROSTATE, SOFT TISSUE, URETHRA AND
BLADDER NECK.

Signature

(Case signed

Signed Others

Frozen Section

A. LEFT AND RIGHT PELVIC NODES: NO TUMOR SEEN.

FS performed by

(Frozen Section Signed

Case Clinical Information

ADENOCARCINOMA OF THE PROSTATE

Gross Description

A. Received in formalin labeled with the patient's name and
"left pelvic lymph nodes FS" are four yellow-tan fibroadipose
tissue fragments measuring 0.9 x 0.7 cm. Wrapped and submitted
in A1.

B. Received in formalin labeled with the patient's name and
"right pelvic lymph nodes FS" are four yellow-tan adipose tissue
fragments measuring 0.7 x 0.7 cm. Wrapped and submitted in B1.

Prepared for

[page 3 of 5]
C. Received in formalin labeled with the patient's name and "left pelvic lymph nodes non-FS" is yellow-tan fibroadipose tissue measuring 2 x 2 cm, consistent with fragmented lymph nodes. Each fragment measures 0.7 x 0.7 cm. Four firm fragments are submitted as follows: two fragments=C1; two fragments=C2; remainder of the adipose tissue entirely submitted in C3.

D. Received in formalin labeled with the patient's name and "right pelvic lymph nodes non-FS" is yellow-tan fibroadipose tissue measuring 2.5 x 2 cm, consistent with a fragmented lymph node. Four firm fragments are grossly identified, measuring 0.7 x 0.7 cm. The specimen is submitted as follows: two fragments=D1; two fragments=D2; remainder of the adipose tissue=D3.

E. Received in formalin labeled with the patient's name, number, and "prostate" is a radical prostatectomy specimen which includes a 24 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 4 x 4 x 3 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 1.5 x 1 cm. The right vas measures 0.9 x 0.4 cm. The left vas measures 0.9 x 0.4 cm. The left seminal vesicle measures 1.5 x 1 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen, and then sectioned from anterior to posterior parallel to the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. The specimen is represented as follows: inferior prostate to demonstrate apical margin submitted entirely anterior to posterior in E1-E4; bladder resection margin is perpendicularly sectioned and entirely submitted in E5-E6; complete section of mid gland anterior E7-E8; posterior E9-E10; complete section of upper third of gland, anterior E11-E12; posterior E13-E14; remainder of the posterior gland entirely submitted in E15-E20; right seminal vesicle and vas deferens represented in E21; left seminal vesicle and vas deferens represented in E22. 90% of the specimen is represented.

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK

H&E X1

B. AA ROUTINE H&E X1 BLOCK

Prepared for

[page 4 of 5]
H&E X1
C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
E. AA ROUTINE H&E X1 BLOCK.5
H&E X1
E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
E. AA ROUTINE H&E X1 BLOCK.7
H&E X1
E. AA ROUTINE H&E X1 BLOCK.8
H&E X1
E. AA ROUTINE H&E X1 BLOCK.9
H&E X1
E. AA ROUTINE H&E X1 BLOCK.10
H&E X1
E. AA ROUTINE H&E X1 BLOCK.11
H&E X1

E. AA ROUTINE H&E X1 BLOCK.12
H&E X1
E. AA ROUTINE H&E X1 BLOCK.13
H&E X1
E. AA ROUTINE H&E X1 BLOCK.14
H&E X1
E. AA ROUTINE H&E X1 BLOCK.15
H&E X1
E. AA ROUTINE H&E X1 BLOCK.16
H&E X1
E. AA ROUTINE H&E X1 BLOCK.17
H&E X1
E. AA ROUTINE H&E X1 BLOCK.18
H&E X1

Prepared for

[page 5 of 5]
E. AA ROUTINE H&E X1 BLOCK.19
H&E X1
E. AA ROUTINE H&E X1 BLOCK.20
H&E X1
E. AA ROUTINE H&E X1 BLOCK.21
H&E X1
E. AA ROUTINE H&E X1 BLOCK.22
H&E X1

Prepared for

Source: NCI Genomic Data Commons file 06d621a6-08c2-494e-8482-185d1b50b997 (TCGA-J4-A67N.70E5E77E-6B59-40A7-8E87-456EF28AED98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).